Gene-level copy-number profile of tumor specimen TCGA-63-A5MV-01A from TCGA case TCGA-63-A5MV, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-63-A5MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f01ccbe2-4564-48a6-b694-08e22aa8e76a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e286e170-4aaf-4d8a-86eb-ca70739915ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 10,857; copy number 2: 26,318; copy number 3: 19,349; copy number 4: 1,364; copy number 5: 582; copy number 6: 332; copy number 7: 538; copy number 8: 126; copy number 9: 68; copy number 10: 24; copy number 11: 34; copy number 12: 1; copy number 13: 105; copy number 24: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MV-01A-21D-A26L-01): tumor purity 0.35, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–11,436,244, 10 genes: AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1.
- chr9:13,738,537–13,744,191, 1 gene: AL158157.1.
- chr9:21,638,285–26,892,803, 49 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31.
- chr9:29,214,322–30,832,225, 12 genes: AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,574 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,045,538–49,419,013, 43 genes, copy number 5 (within-gene range 2–5): STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA.
- chr2:49,233,794–49,233,899, 1 gene, copy number 5: RNU6-439P.
- chr2:98,444,854–99,401,326, 21 genes, copy number 6: INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B.
- chr2:99,405,218–99,405,843, 1 gene, copy number 6: AC018690.1.
- chr3:101,940,859–104,503,266, 12 genes, copy number 5–7 (within-gene range 4–7): LINC02085, AC106712.1, ZPLD1, AC063938.1, RNU6-461P, RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1.
- chr3:177,816,865–190,167,651, 258 genes, copy number 6–13 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–13 (broad region; genes not listed).
- chr7:87,934,143–94,011,113, 90 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:107,168,961–118,004,045, 147 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:37,702,125–39,161,638, 9 genes, copy number 6 (within-gene range 3–6): AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2.
- chr11:48,216,810–54,725,816, 89 genes, copy number 5 (broad region; genes not listed).
- chr19:37,545,470–41,261,766, 193 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
